Gene-level copy-number profile of tumor specimen TCGA-AN-A0FL-01A from TCGA case TCGA-AN-A0FL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-AN-A0FL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.a5ec69cb-1eeb-4a12-bdc6-e7f3b6eaa7df.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0FL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0a087e8d-bfb6-4df1-baec-616d789af43c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 14,518; copy number 2: 28,108; copy number 3: 15,245; copy number 4: 919; copy number 5: 537; copy number 6: 466; copy number 7: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FL-01A-11D-A036-01): tumor purity 0.94, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,015,712–18,513,383, 8 genes: AL357509.1, LINC01654, IGSF21, AL365209.1, IGSF21-AS1, AL591896.1, KLHDC7A, DYNLL1P3.
- chr5:128,083,766–128,189,677, 2 genes (within-gene range 0–1): SLC12A2, KDELC1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,016 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,785,454–7,769,706, 1 gene, copy number 5 (within-gene range 3–5): CAMTA1.
- chr1:7,008,376–11,262,551, 121 genes, copy number 5 (broad region; genes not listed).
- chr1:197,038,741–198,322,420, 18 genes, copy number 5: F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1.
- chr1:234,306,467–238,538,305, 104 genes, copy number 5 (broad region; genes not listed).
- chr3:138,608,606–139,389,736, 21 genes, copy number 5: FAIM, PPIAP72, PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2.
- chr7:17,790,761–20,590,085, 33 genes, copy number 5–6 (within-gene range 4–6): SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13, TWIST1, AC003986.2, AC003986.3, AC003986.1, FERD3L, AC007091.1, POLR1F, MIR3146, TMEM196, AC004543.1, AC005062.1, RPL21P75, AC007001.1, MACC1, MACC1-AS1, AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2.
- chr7:20,641,558–20,641,948, 1 gene, copy number 5: AC002486.1.
- chr8:104,590,733–105,804,539, 1 gene, copy number 5 (within-gene range 4–5): ZFPM2.
- chr8:105,142,860–145,066,685, 587 genes, copy number 5–7 (broad region; genes not listed).
- chr10:4,786,629–4,891,975, 2 genes, copy number 6 (within-gene range 4–6): AKR1E2, AKR1C6P.
- chr10:5,684,838–13,423,133, 127 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,436. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
